Somatic mutation profile of tumor specimen TCGA-QR-A70C-01A (aliquot TCGA-QR-A70C-01A-21D-A35D-08) from TCGA case TCGA-QR-A70C, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 51.0 years (18,628 days).
Specimen TCGA-QR-A70C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6578f628-73a4-4190-b180-af1e1787ca9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70C-10A (Blood Derived Normal), aliquot TCGA-QR-A70C-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53be93e8-8a17-4ee7-972e-fe2d9cab5118

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL6ST | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1200184382; called by muse, mutect2, varscan2
- ZMYND8 | c.914C>T p.A305V (on ENST00000311275 / NM_001363741.2; = p.A325V on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.394); catalogued as COSV53687258; called by muse, mutect2
- ZNF485 | c.1102A>G p.T368A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs1278491103; called by muse, mutect2, varscan2
- ENAM | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- INPP1 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2
- KLHL7 | c.1748C>A p.T583N (on ENST00000339077 / NM_001031710.3; = p.T535N on NM_018846.5) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TOR1AIP1 | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.444); called by muse, mutect2
- ZNF574 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- BEST3 | c.1710C>T p.S570= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs376220817; called by muse, mutect2, varscan2
- MYO1C | c.1470C>T p.I490= (on ENST00000648651 / NM_001080779.2; = p.I455= on NM_033375.5) | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- OGT | c.132C>T p.C44= | Silent (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
